Somatic mutation profile of tumor specimen TCGA-66-2765-01A (aliquot TCGA-66-2765-01A-01W-0877-08) from TCGA case TCGA-66-2765, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.2 years (23,465 days).
Specimen TCGA-66-2765-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fde1890-9bcd-4192-9b14-2172b39b97eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2765-11A (Solid Tissue Normal), aliquot TCGA-66-2765-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/246cba98-cecf-43af-b940-dd3946906a3b

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QB | c.394del p.L132Cfs*12 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs1064797108; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- DICER1 | c.4175G>C p.S1392T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs751216539; called by mutect2, varscan2
- EIF2B2 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as COSV56719793; called by muse, mutect2
- FSTL5 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.013); catalogued as COSV60180843; called by muse, mutect2, varscan2
- KMT2C | c.5803C>T p.P1935S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV51286074; called by muse, mutect2, varscan2
- LCT | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs945583065, COSV51543950; called by muse, mutect2
- MACF1 | c.10043A>T p.N3348I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as COSV57150599; called by muse, mutect2
- OR4C6 | c.373T>A p.C125S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV58602459; called by muse, varscan2
- OR4N2 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV60049916; called by muse, mutect2, varscan2
- PIK3AP1 | c.1685G>T p.S562I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV59530241; called by muse, mutect2, varscan2
- SERPINA4 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs140397956, COSV100097396; called by muse, varscan2
- TTN | c.46732C>A p.Q15578K (on ENST00000591111; = p.Q8154K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | PolyPhen benign (0.006); catalogued as COSV59881276; called by muse, mutect2, varscan2
- UGT1A8 | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV65073161; called by muse, mutect2, varscan2
- UTP20 | c.2134C>G p.P712A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV55371896; called by mutect2, varscan2
- YAP1 | c.1030C>A p.Q344K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV56771743; called by muse, mutect2, varscan2
- SFXN4 | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF311 | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, varscan2
- ACMSD | c.148C>A p.R50= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV51605467, COSV51606661; called by mutect2, varscan2
- AMOTL1 | c.543T>C p.P181= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- EIF3A | c.2973C>T p.N991= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV64960463; called by muse, mutect2, varscan2
- SPATA31D1 | c.696G>A p.K232= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV61192674; called by muse, mutect2, varscan2
- USP24 | c.7146T>C p.H2382= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV53761612; called by muse, mutect2, varscan2
- MIR510 | n.66G>A | RNA (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
